Somatic mutation profile of tumor specimen TARGET-20-PASHWV-09A (aliquot TARGET-20-PASHWV-09A-01D) from TARGET case TARGET-20-PASHWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 23.5 years (8,574 days).
Specimen TARGET-20-PASHWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8deb3436-4c17-4731-aa6e-ed5e4354dfd7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHWV-14A (Bone Marrow Normal), aliquot TARGET-20-PASHWV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33b37348-0584-418d-b7be-8d556f5233af

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 122/304 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CBFB | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by muse, mutect2, varscan2
- ANKRD30A | c.1251C>T p.I417= (on ENST00000611781; = p.I361= on NM_052997.2) | Silent (SNP) | VAF 76/296 reads (26%) | catalogued as rs267602478, COSV64610474; called by muse, mutect2, varscan2
